Somatic mutation profile of tumor specimen 0DPX3T from CCDI case PBCEHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.0 years (6,582 days).
Specimen 0DPX3T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77b47297-8ae6-4793-8456-890e016ac9cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX3C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c54aaa4d-e27b-43d5-a20c-977523375355

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 5, Silent 5, Nonsense Mutation 3, 3'UTR 2, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 257/357 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 151/353 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 137/143 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADGRL1 | c.4154A>G p.Y1385C (on ENST00000340736 / NM_001008701.3; = p.Y1380C on NM_014921.5) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758099966; called by muse, mutect2, varscan2
- ATRX | c.4778C>A p.A1593D | Missense Mutation (SNP) | VAF 210/215 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64883533; called by muse, mutect2, varscan2
- COL4A5 | c.3190G>A p.D1064N | Missense Mutation (SNP) | VAF 203/213 reads (95%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs377337832, COSV60359339; called by muse, mutect2, varscan2
- CRYBG3 | c.6385T>C p.S2129P | Missense Mutation (SNP) | VAF 256/439 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709489; called by muse, mutect2, varscan2
- FER1L5 | c.3577C>T p.R1193W (on ENST00000623019; = p.R1166W on NM_001293083.2) | Missense Mutation (SNP) | VAF 113/219 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs747881322, COSV101208859; called by muse, mutect2, varscan2
- FZD1 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.401); catalogued as COSV99842486; called by muse, mutect2
- GATAD2A | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs760826335, COSV53067156; called by muse, mutect2, varscan2
- MGAM2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 111/246 reads (45%) | catalogued as rs1342252350; called by muse, mutect2, varscan2
- NF1 | c.7739-2A>C p.X2580_splice (on ENST00000358273 / NM_001042492.3; = p.X2559_splice on NM_000267.3) | Splice Site (SNP) | VAF 168/334 reads (50%) | catalogued as CS992460; called by muse, mutect2, varscan2
- SBSN | c.1588G>C p.A530P (on ENST00000452271 / NM_001166034.2; = p.A187P on NM_198538.4) | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV101510051; called by muse, mutect2, varscan2
- SLC6A16 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 117/210 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.374); catalogued as rs769340137, COSV100242761; called by muse, mutect2, varscan2
- STAC2 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs199951266; called by muse, mutect2, varscan2
- ACTL6A | c.199A>T p.T67S | Missense Mutation (SNP) | VAF 74/477 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD65 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CLTC | c.1522-4A>T | Splice Region (SNP) | VAF 271/478 reads (57%) | called by muse, mutect2, varscan2
- COBL | c.3170G>A p.G1057D | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EDC4 | c.2333T>C p.L778P | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESRP2 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 97/262 reads (37%) | called by muse, mutect2, varscan2
- OR4C12 | c.360C>A p.C120* | Nonsense Mutation (SNP) | VAF 137/293 reads (47%) | called by muse, mutect2, varscan2
- TCP11L2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 62/596 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- TXLNB | c.124G>C p.V42L | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FNBP1 | c.804A>C p.V268= | Silent (SNP) | VAF 162/374 reads (43%) | catalogued as COSV63085628; called by muse, mutect2, varscan2
- HTT | c.6666C>G p.A2222= | Silent (SNP) | VAF 137/341 reads (40%) | catalogued as rs1177971019; called by muse, mutect2, varscan2
- NSG1 | c.531G>A p.E177= | Silent (SNP) | VAF 144/308 reads (47%) | called by muse, mutect2, varscan2
- RGS16 | c.177G>A p.V59= | Silent (SNP) | VAF 101/663 reads (15%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 20/646 reads (3%) | called by muse, mutect2
- AC139769.1 | n.214-3988A>G | Intron (SNP) | VAF 130/361 reads (36%) | called by muse, mutect2, varscan2
- C22orf34 | chr22:49626911 G>A | 5'Flank (SNP) | VAF 88/183 reads (48%) | catalogued as rs768968944; called by muse, mutect2, varscan2
- CACYBP | c.15+85T>A | Intron (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- DKK2 | c.530-25C>A | Intron (SNP) | VAF 82/144 reads (57%) | called by muse, mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 9/116 reads (8%) | catalogued as COSV100360835; called by muse, mutect2
- LAMB2 | c.*88C>T | 3'UTR (SNP) | VAF 11/11 reads (100%) | called by mutect2, varscan2
- NLRC5 | c.2627+497A>C | Intron (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2409+18A>G | Intron (SNP) | VAF 16/145 reads (11%) | called by mutect2, varscan2
